Somatic mutation profile of tumor specimen 0DITT2 from CCDI case PBBUPC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 15.8 years (5,766 days).
Specimen 0DITT2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39ec2b0d-e2f4-4947-9048-97d148bbc7df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DITSB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14af8527-a0e5-41c7-9306-1ce5f07dda26

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, Intron 2, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAAT | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 217/934 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs890826564; called by muse, mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 114/643 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- DICER1 | c.1232C>A p.S411* | Nonsense Mutation (SNP) | VAF 331/1465 reads (23%) | catalogued as COSV58620185, COSV58624643; called by muse, mutect2, varscan2
- TCF20 | c.3002T>C p.M1001T | Missense Mutation (SNP) | VAF 174/862 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXS1 | c.297C>T p.H99= | Silent (SNP) | VAF 122/556 reads (22%) | catalogued as rs367844725; called by muse, mutect2, varscan2
- NAV1 | c.294G>A p.T98= | Silent (SNP) | VAF 238/1035 reads (23%) | catalogued as rs769361688; called by muse, mutect2, varscan2
- RWDD2B | c.942T>C p.F314= | Silent (SNP) | VAF 173/783 reads (22%) | catalogued as rs779639678; called by muse, mutect2, varscan2
- AL121899.2 | c.-193G>C | 5'UTR (SNP) | VAF 129/612 reads (21%) | called by muse, mutect2, varscan2
- DSE | c.416+748A>G | Intron (SNP) | VAF 49/278 reads (18%) | called by muse, mutect2
- SAMD4B | c.*43G>A | 3'UTR (SNP) | VAF 117/562 reads (21%) | catalogued as rs555706421; called by muse, mutect2, varscan2
- SUFU | c.1296+67C>T | Intron (SNP) | VAF 164/775 reads (21%) | catalogued as rs1260719894; called by muse, mutect2, varscan2
